Somatic mutation profile of tumor specimen TCGA-4V-A9QW-01A (aliquot TCGA-4V-A9QW-01A-11D-A423-09) from TCGA case TCGA-4V-A9QW, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 62.4 years (22,781 days).
Specimen TCGA-4V-A9QW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f055537-daba-4e39-829a-2641c2a3c873.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4V-A9QW-10A (Blood Derived Normal), aliquot TCGA-4V-A9QW-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e44c78b-d556-4327-88f4-78c3257bd1e1

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 2, Frame Shift Del 1, 3'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 34/487 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- CAMSAP3 | c.1760C>T p.T587M | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs866751877, COSV50334123; called by muse, mutect2
- IGF2BP1 | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV51737008; called by muse, mutect2, varscan2
- ADORA1 | c.395G>A p.W132* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- ARAP3 | c.821C>A p.S274* | Nonsense Mutation (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- ATP9A | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGLV3-27 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.212); called by mutect2, varscan2
- NPR3 | c.678G>T p.E226D | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2
- TFAP2E | c.744del p.E249Sfs*28 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- DSG1 | c.1155T>C p.F385= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as rs768303232; called by muse, mutect2
- SNORD50B | chr6:85677366 A>G | 3'Flank (SNP) | VAF 12/94 reads (13%) | catalogued as rs745709329; called by muse, mutect2, varscan2
